Surgical pathology report (de-identified scan), TCGA case TCGA-77-6842, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-6842-01A (Primary Tumor).

[page 1 of 2]
LEFT LUNG AND LYMPH NODES

Clinical Notes:

L pneumonectomy, number 7 LN, number 5 LN.

Three specimens are received:

1: L LUNG

Macroscopy:

Specimen consists of a left pneumonectomy specimen measuring 300 x 290 x 58 mm in the inflated state. There is an area of adhesion between the upper and lower lobes across the oblique fissure. The pleura otherwise appears normal. Located in the upper lobe 25 mm from the resection margin is a large well circumscribed firm grey mass measuring 62 mm in maximal dimension. It appears to extend across the oblique fissure into the lower lobe. It comes close to the external pleural margin but it appears to be clear of it. The tumour shows central necrosis and cavitation. Near its most medial aspect of the specimen, several lymph nodes show some pale discolouration suggestive of direct invasion by tumour. Adjacent lung tissue shows evidence of mild centri-acinar emphysema. The lung tissue distal to the tumour in the lower lobe shows yellow discolouration suggestive of lipoid pneumonia. [Bronchial resection margin with hilar lymph nodes, 1A; further hilar lymph nodes, 1B; tumour where it appears to cross the oblique fissure, 1C and 1D; tumour with no pleura or margins, 1E; tumour with pleura, 1F; ? lymph node invasion, 1G; emphysema, 1H; ? lipoid pneumonia, 1I].

Microscopy:

Sections show a poorly differentiated carcinoma in which there are some squamous features. The tumour has central necrosis. It invades across the oblique fissure to involve both lobes. Blood vessel invasion is present and there is tumour within an intrapulmonary peribronchial lymph node. The tumour is clear of the bronchial margin. Centriacinar emphysema is noted. Lung distal to the tumour shows patchy organising pneumonia and endogenous lipid pneumonia with collections of intra-alveolar foamy macrophages.

2: NUMBER 5 LYMPH NODE

Macroscopy:

Specimen consists of two grey pieces of tissue which measure 20 x 10 x 3 mm in aggregate. [BIT, 2A].

Microscopy:

The lymph nodes show no evidence of malignancy. The adjacent connective tissue contains nodules of concentric fibrotic tissue consistent with silicotic nodules. These are probably within an obliterated node.

3: NUMBER 7 LYMPH NODE

Macroscopy:

Specimen consists of three tan coloured pieces of tissue measuring 12 x 12 x 3 mm in aggregate. [BIT, 3A].

Microscopy:

The lymph nodes show no evidence of malignancy.

Summary-Specimens 1-3:

Left pneumonectomy and mediastinal lymph nodes:

- 1: Poorly differentiated squamous cell carcinoma of the upper lobe with extension through the oblique fissure into the lower lobe, 62 mm in maximal dimension.
- 2: Peribronchial lymph node involvement.
- 3: Blood vessel and pleural invasion.
- 4: Clear of bronchial resection margin.
- 5: Pathological stage T2N1MX

[page 2 of 2]
Copies:

Source: NCI Genomic Data Commons file ad0470d5-2aab-4279-8de6-4fa7b4fdaca1 (TCGA-77-6842.4F5574A0-E1D7-427C-8F03-D08CB0B264A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).